Surgical pathology report (de-identified scan), TCGA case TCGA-N7-A4Y8, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Washington University, specimen TCGA-N7-A4Y8-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final (

ICD-O-3

Carcinoma / mixed
Mullerian Tumor, malignant
8956/3

Site: Uterus, NOS C559

JW 3/28/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

A. UTERUS WITH CERVIX AND BILATERAL FALLOPIAN TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHERECTOMY

UTERUS:

- MIXED MALIGNANT MESODERMAL TUMOR (MMMT)
- TUMOR INVADERS MYOMETRIUM TO WITHIN 2 MM OF SEROSAL SURFACE
- LYMPHAVASCULAR SPACE INVASION IDENTIFIED
- THE CARCINOMATOUS COMPONENT IS COMPOSED OF HIGH GRADE SEROUS CARCINOMA
- THE SARCOMATOUS COMPONENT SHOWS RHABDOMYOSARCOMATOUS DIFFERENTIATION
- BENIGN LEIOMYOMATA (UP TO 2.5 CM)
- UTERINE SEROSA WITH CARCINOMA DEPOSITION
- CERVIX NOT INVOLVED BY TUMOR
- SEE SYNOPSIS AND COMMENT

BILATERAL OVARIES AND FALLOPIAN TUBES:

- METASTATIC CARCINOMA INVOLVING BILATERAL OVARIAN PARENCHYMA AND PARATUBAL SEROSA AND SOFT TISSUE
- LEFT OVARY ALSO WITH FIBROMA (2.2 CM)

B. SOFT TISSUE, "BLADDER PERITONEAL TUMOR," BIOPSY

- METASTATIC CARCINOMA

C. OMENTUM, GASTROCOLIC, OMENTECTOMY

- METASTATIC CARCINOMA

D. APPENDIX, "WITH CECUM PERITONEUM," APPENDECTOMY WITH PERITONEAL BIOPSY

- METASTATIC CARCINOMA INVOLVEMENT OF PERIAPPENDICEAL SOFT TISSUE AND MUSCULARIS PROPRIA
- TWO PERIAPPENDICEAL LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/2)
- METASTATIC CARCINOMA INVOLVING "CECUM PERITONEUM"

E. SOFT TISSUE, "RECTAL SEROSAL TUMOR," BIOPSY

- METASTATIC CARCINOMA

F. SOFT TISSUE, "PELVIC PERITONEUM," BIOPSY

- METASTATIC CARCINOMA

Page 1 of 5

Page: 1 of 5

[page 2 of 5]
Patient Name: [REDACTED]

SURGICAL PATHOLOGY REPORT

G SOFT TISSUE, "RECTAL TUMOR," BIOPSY
- METASTATIC CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out by I

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick-up 'uterus, cervix, bilateral tubes and ovaries' consisting of 935 gram hysterectomy with bilateral salpingo-oophorectomy specimen. The uterus measures 15 x 13 x 11 cm with smooth serosal surface. Opened to show a large mass (14 x 12.5 x 10 cm) arising from uterine fundus. Mass is heterogeneous tan-brown and white, soft, partially cystic. Sampled for study. In operating room, right adnexa is attached to uterus, left adnexa is separated from uterus. Both adnexae are unremarkable. Rest for permanents," by "

Microscopic Description and Comment:

The endometrial mass consists of a biphasic tumor composed of a sarcomatous element consisting of a high grade serous carcinoma and sarcomatous element with rhabdomyosarcomatous differentiation. Multiple immunohistochemical stains were performed on 2 different blocks. The sarcomatous tumor cells were strongly and diffusely positive for p16. The sarcomatous tumor cells were focally positive for desmin, smooth muscle actin and myogenin. Tumor cells were negative for ER, PR, pancytokeratin, EMA and CAM 5.2. These immunostains confirm the rhabdomyosarcomatous component.

History:

The patient is a [REDACTED] year old Caucasian woman with history of mixed malignant mesodermal tumor on endometrial biopsy. Operative procedure: Examination under anesthesia, total abdominal hysterectomy and bilateral salpingo-oophorectomy.

Specimen(s) Received:

A: UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES
B: BLADDER PERITONEAL TUMOR
C: OMENTUM, GASTRIC COLIC
D: APPENDIX WITH CECAL PERITONEUM
E: RECTAL SEROSAL TUMOR
F: PELVIC PERITONEUM
G: RECTAL TUMOR

Gross Description:

The specimens are received in seven formalin-filled containers labeled "[REDACTED]". The first container is also labeled "uterus, cervix, bilateral tubes and ovaries." It contains a previously bivalved and sectioned hysterectomy with bilateral salpingo-oophorectomy specimen consistent with the intraoperative non-microscopic consultation. The

[page 3 of 5]
Patient Name: [REDACTED]

SURGICAL PATHOLOGY REPORT

formalin-filled specimen is markedly distorted but when examined fresh measured 15.0 x 13.0 x 11.0 cm. The serosal surface is smooth. The cervix measures 2.1 x 2.0 cm. The ectocervix has a tan-brown, glistening mucosa with no gross lesions seen. The endocervical canal has a tan appearance and measures 2.7 cm in length. The endometrial cavity is difficult to measure secondary to marked distortion, but appears to measure at least 9.0 cm from cornu-to-cornu by 6.5 cm in length. The endometrial cavity is filled by the previously described large polypoid mass measuring 14.0 x 12.5 x 10.0 cm. The mass is multilobulated and multicystic with abundant areas of green-tan necrosis and friable tan, solid areas. The mass appears to originate from the fundus and the superior aspect of the anterior endometrium involving the anterior myometrium. The remainder of the endometrial mucosa has a rough, nodular appearance. The myometrium is thinned in multiple areas and has multiple nodules present within the anterior aspect which appear to be contiguous with the lesion. The largest of these nodules measure 3.0 cm in greatest dimension. The nodules extend to within 0.3 cm of the serosal surface which is smooth and glistening. The myometrium measures up to 1.2 cm in greatest thickness. Multiple additional firm nodules are present in the posterior aspect of the myometrium. These nodules have a well-circumscribed firm, tan-white, whorled appearance. The largest of these nodules measure 0.6 cm in greatest dimension. The anterior myometrium is also involved by multiple firm well-circumscribed, tan-white, whorled-appearing nodules with abundant calcification. The nodules measure up to 2.5 cm in greatest dimension. The right fallopian tube and ovary are still attached to the uterus. The right fallopian tube measures 6.5 x 0.6 x 0.5 cm and has a fimbriated end. The tube is sectioned to show a pinpoint lumen with no additional lesions seen. The right ovary is atrophic and measures 1.6 x 0.8 x 0.6 cm. The serosal surface is tan-white and smooth. The ovary is bisected to show a tan-white mottled parenchyma with no lesions seen. The left fallopian tube and ovary are detached and present in the container. The left fallopian tube measures 4.5 x 0.9 x 0.7 cm and has a fimbriated end. The tube is sectioned to show a pinpoint lumen with no lesions seen. The ovary measures 2.5 x 1.2 x 0.8 cm and has a pedunculated firm nodular mass attached which measures 2.2 x 1.6 x 1.0 cm. The ovary is sectioned to show a white-tan, mottled-appearing parenchyma with no gross lesions seen. The pedunculated para-ovarian mass is sectioned to show a whorled, firm, white, solid appearance. The uterus is submitted as follows: A1 - anterior cervix; A2 - contiguous section of anterior lower uterine segment; A3 - contiguous segment of anterior endomyometrium; A4 - contiguous segment of anterior endomyometrium; A5 - posterior cervix; A6 - contiguous section of posterior lower uterine segment; A7 and A8 - contiguous sections of posterior endomyometrium; A9 through A13 - sections of anterior endomyometrium with associated mass; A14 to A15 - fundus with associated mass; A16 - fundus with adjacent posterior endomyometrium and associated mass; A17 - posterior endomyometrium; A18 through A25 - sections of large mass with adjacent areas of necrosis and hemorrhage; A26 - right fallopian tube; A27 - right ovary (entirely submitted); A28 - left fallopian tube; A29 - left ovary (entirely submitted); A30 to A33 - para-ovarian mass entirely submitted. Jar 4.

The second container is labeled "bladder peritoneal tumor." It contains a white-tan irregular fragment of tissue measuring 2.0 x 0.5 x 0.3 cm. The specimen is entirely submitted as B1. Jar 0.

The third container is labeled "gastrocolic omentum." It contains an irregular lobulated yellow-brown fragment of fatty tissue measuring 53.0 x 7.0 x 1.5 cm. The tissue is consistent with omentum and has a firm, nodular appearance to the majority of the omental tissue. The omentum is sectioned to show an infiltrative white appearance to a majority of the fatty tissue with many areas coalescing to form nodules. The largest well-circumscribed nodule measures 1.5 x 1.0 x 1.5 cm. Random sections of the nodular areas are submitted as C1 to C4.

The fourth container is labeled "appendix with cecal peritoneum." It contains multiple irregular fragments of yellow-brown tissue measuring 8.0 x 6.0 x 2.5 cm in aggregate. One of the fragments represents appendix with attached periappendiceal adipose tissue. The appendix measures 5.5 cm in length x 1.0 x 0.5 cm. The serosa is rough and irregular with multiple areas of hemorrhage and adhesions. The appendix is sectioned to show an unremarkable star-shaped lumen with minimal amount of fecal material present. A firm, well-circumscribed white area is present in the adjacent periappendiceal adipose tissue which measures 0.5 x 0.3 x 0.2 cm. The additional fragments of tissue are irregular, yellow-brown and appear to represent adipose tissue with glistening peritoneal surfaces. The tissues are sectioned to show well-circumscribed firm, white areas. The largest of the firm white areas measure 3.0 x 1.5 x 0.5 cm. The specimen is submitted as follows: D1 - representative sections of appendix; D2 and D3 - additional submitted tissue. Jar 1.

The fifth container is labeled "rectal serosal tumor." It contains multiple irregular tan-white firm fragments of tissue measuring 4.5 x 2.0 x 0.5 cm in aggregate. The fragments of tissue have an irregular and somewhat friable appearance. The fragments of tissue range from 0.5 x 0.3 x 0.2 to 1.8 x 1.2 x 0.4 cm. The specimen is entirely submitted in E1 and E2. Jar 0.

The sixth container is labeled "pelvic peritoneum." It contains multiple irregular yellow and brown fragments of tissue measuring 10.0 x 9.0 x 2.5 cm in aggregate. The fragments range in size from 1.5 x 0.9 x 0.5 to 11.5 x 4.5 x 1.2 cm. The fragments have a heterogeneous appearance with areas of fibroadipose tissue and glistening firm, thickened

[page 4 of 5]
Patient Name: [REDACTED]

SURGICAL PATHOLOGY REPORT

areas consistent with peritoneum. These areas have marked thickening in some of the fragments and measure up to 0.3 cm in greatest thickness. Representative sections are submitted as F1 to F3. Jar 2.

The seventh container is labeled "rectal tumor." It contains multiple irregular yellow and brown irregular tissue fragments measuring 5.0 x 4.0 x 1.8 cm in aggregate. The tissue fragments range from 0.6 x 0.3 x 0.3 cm to 5.0 x 2.5 x 1.2 cm. The fragments all have a similar heterogeneous appearance with areas of yellow adipose tissue intermixed with firm, white-gray areas. The firm white-gray areas measure up to 3.0 x 2.0 x 0.4 cm. Representative sections are submitted as G1 through G2. Jar 2.

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

Uterus

HISTOPATHOLOGIC TYPE

The histologic diagnosis is malignant mixed müllerian tumor with heterologous stromal elements including rhabdomyosarcomatous elements

FIGO GRADE

The FIGO Grade of the tumor is 51 to 100% solid growth pattern (FIII)

TUMOR INVASION

Invasive tumor is present with invasion of the outer 1/3 of the myometrium

TUMOR SIZE

Tumor invades myometrium to within 2 mm of serosa

LOWER UTERINE SEGMENT INVOLVEMENT

(does not change the stage)

The lower uterine segment is involved by tumor

ENDOCERVICAL INVOLVEMENT

The endocervix is not involved by tumor

LYMPHVASCULAR SPACE INVASION

Lymphovascular space invasion by tumor is present

REGIONAL LYMPH NODES (N)

Regional lymph nodes metastasis to pelvic lymph nodes (N1/III C1)

The regional lymph nodes are involved by tumor in 2 nodes

The total number of lymph nodes examined is 2

Extranodal extension by tumor metastases is absent

DISTANT METASTASIS (M)

Distant metastases (M1)

A biopsy of the metastatic site was performed

The source of pathologic metastatic specimen is bladder peritoneum, omentum, large intestine serosa, pelvic peritoneum

PRIMARY TUMOR (TNM Category/FIGO Stage)

Distant metastasis includes metastasis to inguinal lymph nodes, intraperitoneal disease, or lung, liver or bone. It excludes metastasis to para-aortic lymph nodes, vagina, pelvic serosa or adnexa (M1/IVB)

STAGE GROUPING

The overall pathologic AJCC stage of the tumor is pT4/N1/M1

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 5 of 5]
Patient Name:

SURGICAL PATHOLOGY REPORT

END OF REPORT

Page 5 of 5

Page: 5 of 5

Criteria	pw 2/7/13	Yes	No
Dual/Synchronous Primary (Dual)			✓

Source: NCI Genomic Data Commons file f922a954-79c7-40bd-9d70-bf896e18926f (TCGA-N7-A4Y8.BFA19641-03C8-49B1-B4F9-CAC9E4C3DC76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).